Gene-level copy-number profile of tumor specimen ALCH-B3DX-TTP1-A from ALCHEMIST case ALCH-B3DX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 54.1 years (19,754 days).
Specimen ALCH-B3DX-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 78f7f699-0041-4a6f-aff0-442d46bbbfed.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3DX-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,706 have no estimate.
https://portal.gdc.cancer.gov/files/d39602a1-b11a-4530-8348-4c9e42875aa3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,927; copy number 2: 55,330; copy number 3: 658; copy number 8: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:33,976,039–33,991,551, 2 genes, copy number 8 (within-gene range 2–8): AC133561.1, BCAP31P1.

Autosomal genes at a single copy (total copy number 1): 71. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
